Somatic mutation profile of tumor specimen TCGA-DD-A3A5-01A (aliquot TCGA-DD-A3A5-01A-11D-A22F-10) from TCGA case TCGA-DD-A3A5, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 66.5 years (24,288 days).
Specimen TCGA-DD-A3A5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74c805ee-fc0f-4d34-9f28-9d24c5b4ab14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A3A5-11A (Solid Tissue Normal), aliquot TCGA-DD-A3A5-11A-11D-A22F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45d34488-4117-4464-a359-ac16de638f8c

The open-access MAF lists 64 somatic variants for this specimen: 49 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 14, Nonsense Mutation 6, Frame Shift Del 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADARB2 | c.65C>G p.S22C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1257430231, COSV67235647; called by muse, mutect2
- ALK | c.699G>T p.M233I | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV101200703, COSV66587772; called by muse, mutect2, varscan2
- APOB | c.1681G>T p.A561S | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV51950547; called by muse, mutect2, varscan2
- BICD1 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 26/75 reads (35%) | catalogued as COSV55687304; called by muse, mutect2, varscan2
- C3AR1 | c.172A>G p.T58A | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50823676; called by muse, mutect2, varscan2
- CARD8 | c.1306G>T p.D436Y (on ENST00000651546 / NM_001184900.3; = p.D386Y on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV62875086; called by muse, mutect2, varscan2
- CDH5 | c.1705A>G p.S569G | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV58519722; called by muse, mutect2, varscan2
- CEACAM6 | c.866T>C p.I289T | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV52269101; called by muse, mutect2, varscan2
- CRB1 | c.4030A>G p.I1344V | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs111761880; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DEPDC7 | c.10G>A p.V4M | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV53809160; called by muse, mutect2, varscan2
- DHX57 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 39/110 reads (35%) | catalogued as rs1231718000, COSV54884842; called by muse, mutect2, varscan2
- DMBT1 | c.6170G>C p.G2057A (on ENST00000338354 / NM_001377530.1; = p.G1300A on NM_004406.3) | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100352918, COSV57533673, COSV57559889; called by muse, mutect2, varscan2
- DNAJC1 | c.657G>A p.W219* | Nonsense Mutation (SNP) | VAF 29/64 reads (45%) | catalogued as COSV65376807; called by muse, mutect2, varscan2
- E2F3 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs1480011422, COSV60899646; called by muse, mutect2, varscan2
- EMC1 | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.171); catalogued as COSV61887093; called by muse, varscan2
- EP400 | c.2113C>T p.R705W | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs779657584, COSV57774563; called by muse, mutect2, varscan2
- FAHD2A | c.631T>C p.F211L | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.145); catalogued as COSV51979102; called by muse, mutect2, varscan2
- FGGY | c.1537G>T p.V513F | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.187); catalogued as COSV58044693; called by muse, mutect2, varscan2
- FLNB | c.265C>G p.R89G | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs755518501, COSV55894104; called by muse, mutect2, varscan2
- GAST | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs868921087, COSV61475603, COSV61475819; called by muse, mutect2, varscan2
- GCN1 | c.5889G>T p.E1963D | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.468); catalogued as rs1358396940, COSV56114290; called by muse, mutect2, varscan2
- GNG12 | c.94-1G>C p.X32_splice | Splice Site (SNP) | VAF 33/140 reads (24%) | catalogued as COSV63973917; called by muse, mutect2, varscan2
- IFNG | c.99C>G p.N33K | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV57492011; called by muse, mutect2, varscan2
- IGSF9B | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1369676278, COSV58072337; called by muse, mutect2
- JMJD8 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 52/85 reads (61%) | SIFT tolerated (0.75); PolyPhen benign (0.033); catalogued as COSV50203796; called by muse, mutect2, varscan2
- KCNS3 | c.802G>T p.A268S | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as COSV58405581; called by muse, mutect2, varscan2
- KLRK1 | c.556A>T p.K186* | Nonsense Mutation (SNP) | VAF 56/143 reads (39%) | catalogued as COSV53699756; called by muse, mutect2, varscan2
- LDAH | c.508A>G p.M170V | Missense Mutation (SNP) | VAF 103/164 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV52973233; called by muse, mutect2, varscan2
- M1AP | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs956996083, COSV51213253; called by muse, mutect2, varscan2
- NEK9 | c.887G>A p.R296K | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53133415; called by muse, mutect2, varscan2
- OR51E1 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs137885627, COSV67810896; called by muse, mutect2, varscan2
- OR56B4 | c.471G>T p.R157S | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57205486; called by muse, mutect2, varscan2
- PCDHGA5 | c.1273A>G p.M425V | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1198770505, COSV54022190; called by muse, mutect2, varscan2
- PDE4DIP | c.1988C>T p.A663V | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.142); catalogued as COSV57725962; called by muse, mutect2, varscan2
- PLA2G4F | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs776310395, COSV51829024; called by muse, mutect2, varscan2
- PYCARD | c.506G>A p.W169* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV56008290; called by muse, mutect2, varscan2
- RASD1 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51958395; called by muse, mutect2, varscan2
- RSC1A1 | c.401C>A p.S134Y | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60781347; called by muse, mutect2, varscan2
- RUFY4 | c.1145C>T p.T382I | Missense Mutation (SNP) | VAF 73/142 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.296); catalogued as COSV60249315; called by muse, mutect2, varscan2
- RYR2 | c.4469C>T p.A1490V | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.201); catalogued as COSV63679382, COSV63702770; called by muse, mutect2, varscan2
- SMARCA1 | c.889A>T p.K297* | Nonsense Mutation (SNP) | VAF 132/328 reads (40%) | catalogued as COSV64413629; called by muse, mutect2, varscan2
- THSD7A | c.471G>C p.E157D | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs768533858, COSV70264892, COSV70271865; called by muse, mutect2, varscan2
- TPCN1 | c.329T>C p.L110P | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV59238380; called by muse, mutect2, varscan2
- TSHZ1 | c.1114G>A p.A372T (on ENST00000580243 / NM_001308210.2; = p.A327T on NM_005786.6) | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs574385316, COSV59016332; called by muse, mutect2, varscan2
- UBA6 | c.510C>G p.I170M | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100451573, COSV59175638, COSV59180793; called by muse, mutect2, varscan2
- ZNF534 | c.230G>A p.R77K (on ENST00000332323 / NM_001143939.3; = p.R64K on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV56520640, COSV99989638; called by muse, mutect2, varscan2
- DUSP14 | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIK3C2B | c.4827_4840del p.R1610Gfs*75 | Frame Shift Del (DEL) | VAF 32/78 reads (41%) | called by mutect2, varscan2
- ZNF132 | c.1941_1942del p.R647Sfs*9 | Frame Shift Del (DEL) | VAF 23/78 reads (29%) | called by pindel, varscan2
- DNAH17 | c.8817G>T p.R2939= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV67760561; called by muse, mutect2, varscan2
- HTR1A | c.1077G>A p.L359= | Silent (SNP) | VAF 52/104 reads (50%) | catalogued as COSV60502807; called by muse, mutect2, varscan2
- KCNA2 | c.150C>A p.T50= | Silent (SNP) | VAF 45/99 reads (45%) | catalogued as COSV60371362; called by muse, mutect2, varscan2
- MIS18BP1 | c.1545T>C p.D515= | Silent (SNP) | VAF 98/244 reads (40%) | catalogued as COSV60373250; called by muse, mutect2, varscan2
- MISP | c.1224C>T p.A408= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs530131211, COSV53122130; called by muse, mutect2, varscan2
- MNDA | c.183T>C p.C61= | Silent (SNP) | VAF 63/150 reads (42%) | catalogued as COSV63742009; called by muse, mutect2, varscan2
- MRPL53 | c.267C>G p.A89= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as COSV50688961; called by muse, mutect2, varscan2
- NGLY1 | c.303T>A p.I101= | Silent (SNP) | VAF 89/211 reads (42%) | catalogued as COSV54990646; called by muse, mutect2, varscan2
- NRXN3 | c.1665C>A p.I555= (on ENST00000557594 / NM_001272020.2; = p.I979= on NM_004796.6) | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as COSV55322616; called by muse, mutect2, varscan2
- SGSM1 | c.1638C>A p.I546= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as COSV68513188, COSV68514418; called by muse, mutect2, varscan2
- SIMC1 | c.969G>T p.V323= (on ENST00000443967 / NM_001308196.1; = p.V342= on NM_001308195.2) | Silent (SNP) | VAF 69/166 reads (42%) | catalogued as COSV100365708; called by muse, mutect2, varscan2
- SPTBN1 | c.3681T>C p.A1227= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as COSV61687465, COSV61693584; called by muse, mutect2, varscan2
- TAOK3 | c.841C>A p.R281= | Silent (SNP) | VAF 39/111 reads (35%) | catalogued as COSV66827587; called by muse, mutect2, varscan2
- ZNF385C | c.1350C>A p.I450= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV56918427; called by muse, mutect2, varscan2
- MIR583 | n.66C>T | RNA (SNP) | VAF 39/88 reads (44%) | catalogued as rs749248154; called by muse, mutect2, varscan2
